Gene-level copy-number profile of tumor specimen TCGA-ER-A19W-06A from TCGA case TCGA-ER-A19W, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.7 years (21,798 days).
Specimen TCGA-ER-A19W-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.67877777-25a3-498f-8638-d4e3f2c05741.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4092302-b78d-4e91-8ab2-5aefe8f21f38

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 2: 16,795; copy number 3: 7,031; copy number 4: 31,599; copy number 5: 1,600; copy number 6: 896; copy number 7: 1,335; copy number 8: 224; copy number 10: 152; copy number 12: 3; copy number 17: 54; copy number 24: 37; copy number 36: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19W-06A-41D-A238-01): tumor purity 0.37, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:78,134,079–78,359,458, 3 genes: AC004808.2, AC004808.1, RPL13AP17.
- chr9:21,077,104–22,214,672, 53 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 277 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,052,859–69,654,474, 37 genes, copy number 24 (within-gene range 2–24): CHKA, AP002992.1, KMT5B, C11orf24, AP002813.1, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1.
- chr11:69,809,968–69,926,813, 3 genes, copy number 12: FGF3, AP007216.1, AP007216.2.
- chr11:72,576,141–72,674,591, 1 gene, copy number 36 (within-gene range 4–36): PDE2A.
- chr11:72,621,766–75,018,893, 84 genes, copy number 17–36 (broad region; genes not listed).
- chr18:47,390–7,461,135, 150 genes, copy number 10 (broad region; genes not listed).
- chr18:7,741,310–7,815,730, 2 genes, copy number 10: AP000897.2, AP000897.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
